Somatic mutation profile of tumor specimen 0DUUQA from CCDI case PBCLYG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.7 years (5,727 days).
Specimen 0DUUQA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4225eb96-afe1-4498-a024-9d40101d8532.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUUPR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af0506e0-ba68-4d2e-8066-e62f89c2fe0d

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR4C5 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 47/609 reads (8%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.029); catalogued as rs72898877; called by muse, mutect2
- RABGGTA | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368437109; called by muse, mutect2, varscan2
- SFRP4 | c.812G>T p.C271F | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs1267591810; called by muse, mutect2
- SHD | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 113/364 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs201753889; called by muse, mutect2, varscan2
- DNAH14 | c.9667A>C p.K3223Q (on ENST00000445597; = p.K4231Q on NM_001367479.1) | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- IL17RB | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 39/357 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ACTR10 | c.1050T>C p.A350= | Silent (SNP) | VAF 9/157 reads (6%) | catalogued as rs1441642162; called by muse, mutect2
- CD86 | c.9C>G p.P3= | Silent (SNP) | VAF 24/368 reads (7%) | called by muse, mutect2
- UBE2B | c.242-35A>T | Intron (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
